Somatic mutation profile of tumor specimen TCGA-DD-AAE3-01A (aliquot TCGA-DD-AAE3-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 50.0 years (18,271 days).
Specimen TCGA-DD-AAE3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f7aa205-fbc2-4cc2-94e9-c0d77054b7a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE3-10A (Blood Derived Normal), aliquot TCGA-DD-AAE3-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1a10b6b-c5b6-48fd-aaaa-27ee39c775bb

The open-access MAF lists 179 somatic variants for this specimen: 139 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 38, Frame Shift Del 9, Splice Site 5, Nonsense Mutation 5, In Frame Del 2, Intron 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 14/93 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- ADH4 | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99644212; called by muse, mutect2, varscan2
- AFAP1L1 | c.2287T>A p.W763R | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV99695919; called by muse, mutect2, varscan2
- AK9 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as rs372325726; called by muse, mutect2, varscan2
- ANKRD10 | c.59T>G p.L20R | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99941143; called by muse, mutect2, varscan2
- AP1G1 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs779499602, COSV100250484; called by muse, mutect2, varscan2
- APC | c.4669A>G p.I1557V | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs763578917, CD041153, COSV57352657; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- ASTL | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV100668358; called by muse, mutect2
- ATG2B | c.4829T>C p.I1610T | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99952081; called by muse, mutect2, varscan2
- ATP13A1 | c.803T>G p.F268C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV99366208; called by muse, mutect2
- ATRX | c.7033G>A p.V2345M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.107); catalogued as COSV64876403, COSV64879345; called by muse, mutect2, varscan2
- C1QL2 | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV99733212; called by muse, mutect2, varscan2
- C1QTNF12 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs754889120, COSV100382593; called by muse, mutect2, varscan2
- C3 | c.814A>G p.I272V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV99836710; called by muse, mutect2, varscan2
- CCT5 | c.595A>G p.M199V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99725374; called by muse, mutect2, varscan2
- CDH1 | c.1904G>T p.S635I | Missense Mutation (SNP) | VAF 57/86 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as COSV99932017; called by muse, mutect2, varscan2
- CDHR1 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1424495418, CM162524, COSV100258914; called by muse, mutect2, varscan2
- CEACAM4 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368076616; called by muse, mutect2, varscan2
- CEP68 | c.2036A>C p.Q679P | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99560964; called by muse, mutect2, varscan2
- CGNL1 | c.1709A>G p.N570S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV99848403; called by muse, mutect2, varscan2
- CHUK | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100957136; called by muse, mutect2, varscan2
- CLTC | c.3233A>G p.N1078S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs759911857, COSV99292355; called by muse, mutect2, varscan2
- CNTNAP2 | c.1778-2A>G p.X593_splice | Splice Site (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100666943; called by muse, mutect2, varscan2
- COG7 | c.1085A>T p.Y362F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100207580; called by muse, mutect2, varscan2
- COL11A1 | c.3758A>T p.E1253V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100616787; called by muse, mutect2, varscan2
- COPB1 | c.2026C>G p.L676V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99999629; called by muse, mutect2, varscan2
- COX11 | c.737A>C p.D246A | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174039; called by muse, mutect2, varscan2
- CRYBG3 | c.8600T>C p.I2867T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV99477041; called by muse, mutect2, varscan2
- DDI1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV100159330, COSV56390718; called by muse, mutect2, varscan2
- DDX46 | c.828T>G p.D276E | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100844884; called by muse, mutect2, varscan2
- DENND4A | c.2117A>G p.N706S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV101475356; called by muse, mutect2, varscan2
- DNAH5 | c.3812_3813insT p.F1272Lfs*7 | Frame Shift Ins (INS) | VAF 12/112 reads (11%) | catalogued as COSV99450361; called by mutect2, pindel, varscan2
- DNASE1L2 | c.577A>C p.K193Q | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV100065804; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1423A>G p.M475V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99263034; called by muse, mutect2
- EGFR | c.2230A>G p.I744V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs1554348865, COSV104369002, COSV51766284; called by muse, mutect2, varscan2
- EPHB3 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57805265; called by muse, mutect2, varscan2
- ERMAP | c.518T>G p.L173R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.276); catalogued as COSV100072257; called by muse, mutect2, varscan2
- ERO1B | c.314T>G p.I105S | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV100524074; called by muse, mutect2, varscan2
- ERP29 | c.713A>C p.K238T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99923604; called by muse, mutect2, varscan2
- FAM98B | c.676A>G p.M226V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as COSV99989104; called by muse, mutect2, varscan2
- FMR1 | c.559A>T p.M187L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV99503333; called by muse, mutect2, varscan2
- FRAS1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1353392763, COSV99352551; called by muse, mutect2, varscan2
- GABPB2 | c.391del p.H131Mfs*13 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | catalogued as COSV64461220; called by mutect2, pindel, varscan2
- GCC2 | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.071); catalogued as COSV100565466; called by muse, mutect2, varscan2
- GDI2 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100050462, COSV100050545; called by muse, mutect2, varscan2
- GEMIN5 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as COSV53565870; called by muse, mutect2, varscan2
- GHITM | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100930090; called by muse, mutect2, varscan2
- GLIPR1 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV99875705; called by muse, mutect2, varscan2
- GLRA2 | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.973); catalogued as COSV99491139; called by muse, mutect2, varscan2
- HNRNPC | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.065); catalogued as COSV100193131; called by muse, mutect2, varscan2
- IDE | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs768663201, COSV99794033; called by muse, mutect2, varscan2
- IREB2 | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV99359434; called by muse, mutect2, varscan2
- ITK | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV101439759; called by muse, mutect2, varscan2
- ITPR3 | c.4720C>T p.R1574W | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs531158838, COSV100967414; called by muse, mutect2, varscan2
- ITPR3 | c.6070G>C p.E2024Q | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.999); catalogued as COSV100967415; called by muse, mutect2
- JMJD1C | c.7328A>G p.Y2443C | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs777189076, COSV100550590; called by muse, mutect2, varscan2
- KIZ | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV99852101; called by muse, mutect2, varscan2
- KMT2C | c.14047G>C p.A4683P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100072445; called by muse, mutect2, varscan2
- KPNA2 | c.1088C>G p.T363R | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100388784; called by muse, mutect2, varscan2
- KPNB1 | c.1769A>G p.N590S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99268147; called by muse, mutect2, varscan2
- KRT26 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.034); catalogued as COSV100156514; called by muse, mutect2, varscan2
- KRT5 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99358051; called by muse, mutect2, varscan2
- KRTAP24-1 | c.622T>A p.Y208N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV100447437; called by muse, mutect2, varscan2
- LRP1 | c.84C>G p.S28R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV99675996; called by muse, mutect2, varscan2
- MAN2A1 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 66/476 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99811263; called by muse, mutect2, varscan2
- MAPK6 | c.1184A>G p.Q395R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99959216; called by muse, mutect2, varscan2
- MED17 | c.360G>C p.R120S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99316034; called by muse, mutect2, varscan2
- MGA | c.1693A>G p.I565V | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99580156; called by muse, mutect2, varscan2
- MRPL13 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs145547223; called by muse, mutect2, varscan2
- MVD | c.811T>G p.F271V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99879933; called by muse, mutect2, varscan2
- MYO9B | c.5677G>C p.E1893Q | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.122); catalogued as COSV101261593; called by muse, mutect2
- NOS1 | c.3976-2A>G p.X1326_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100500699; called by muse, mutect2
- NRAS | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs114636410, COSV54738995; called by muse, mutect2, varscan2
- NUP155 | c.4169T>G p.L1390R (on ENST00000231498 / NM_153485.3; = p.L1331R on NM_004298.4) | Missense Mutation (SNP) | VAF 49/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99192961; called by muse, mutect2, varscan2
- OPCML | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100101801; called by muse, mutect2, varscan2
- OR2B11 | c.247C>G p.P83A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV100276147, COSV59509787; called by muse, mutect2, varscan2
- OR5K1 | c.92T>A p.F31Y | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100220967; called by muse, mutect2, varscan2
- PALMD | c.1223A>G p.N408S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99586408; called by muse, mutect2, varscan2
- PCNX1 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99455777; called by muse, mutect2, varscan2
- PDZD2 | c.1126G>C p.G376R | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225191; called by muse, mutect2, varscan2
- PJA2 | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV100754461; called by muse, mutect2
- PNPLA5 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs768114170, COSV99336643; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.398A>T p.Q133L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV99461349; called by muse, mutect2, varscan2
- PPDPF | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs1013356789, COSV100925640; called by muse, mutect2, varscan2
- PPIP5K2 | c.2513A>G p.Y838C | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100383901; called by muse, mutect2
- PUM3 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as rs552128111, COSV101193188; called by muse, mutect2, varscan2
- RAI14 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs565597265, COSV99463288; called by muse, mutect2, varscan2
- RB1CC1 | c.4510G>T p.G1504* | Nonsense Mutation (SNP) | VAF 51/101 reads (50%) | catalogued as COSV99212303; called by muse, mutect2, varscan2
- REST | c.2884A>G p.I962V | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100471034; called by muse, mutect2, varscan2
- RNF20 | c.1673A>G p.N558S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs750558519, COSV101206535; called by muse, mutect2, varscan2
- RWDD2A | c.811A>T p.K271* | Nonsense Mutation (SNP) | VAF 74/172 reads (43%) | catalogued as COSV52286200, COSV99392399; called by muse, mutect2, varscan2
- SDE2 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99682691; called by muse, mutect2, varscan2
- SDF2L1 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1014770028, COSV99963647; called by muse, mutect2, varscan2
- SEPHS2 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101529326; called by muse, mutect2, varscan2
- SF3B1 | c.962A>T p.D321V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100134824; called by muse, mutect2, varscan2
- SGMS1 | c.781A>C p.K261Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV100693408; called by muse, mutect2, varscan2
- SIGLEC1 | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs766676495, COSV99166075; called by muse, mutect2, varscan2
- SLC1A7 | c.431+1G>T p.X144_splice | Splice Site (SNP) | VAF 34/56 reads (61%) | catalogued as rs1212141950, COSV101019634; called by muse, mutect2, varscan2
- SLC25A40 | c.429A>G p.I143M | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100353700, COSV62020751; called by muse, mutect2, varscan2
- SLC26A7 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99403470; called by muse, mutect2, varscan2
- SLC38A2 | c.1456A>G p.M486V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99873933; called by muse, mutect2, varscan2
- SLCO1B3 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 172/236 reads (73%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs374152690; called by muse, mutect2, varscan2
- SLITRK5 | c.2474G>T p.S825I | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100280816; called by muse, mutect2, varscan2
- SNRPN | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV100578252; called by muse, mutect2
- SPPL3 | c.719A>C p.N240T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100793649; called by muse, mutect2, varscan2
- SPSB1 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100049501; called by muse, mutect2, varscan2
- SRSF4 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs368357249; called by muse, mutect2, varscan2
- SUPT3H | c.78A>T p.K26N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100177307; called by muse, mutect2, varscan2
- SYMPK | c.2638C>G p.L880V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99841763; called by muse, mutect2, varscan2
- TGFB1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs201383660, COSV99700195; called by muse, mutect2, varscan2
- TOP3A | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100329110; called by muse, mutect2, varscan2
- TRNT1 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.053); catalogued as rs1201044380, COSV52409307; called by muse, mutect2, varscan2
- TSGA10 | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1245606269, COSV100747567; called by muse, mutect2, varscan2
- TXLNA | c.1593A>C p.E531D | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101009865; called by muse, mutect2, varscan2
- TXNIP | c.337T>A p.S113T | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV100997299; called by muse, mutect2, varscan2
- UBE4B | c.1786A>T p.S596C (on ENST00000343090 / NM_001105562.3; = p.S467C on NM_006048.5) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99476748; called by muse, mutect2, varscan2
- UBFD1 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV54841842, COSV99563288; called by muse, mutect2, varscan2
- VPS13B | c.512T>A p.V171D | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100662171; called by muse, mutect2, varscan2
- VRTN | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as COSV56443554, COSV56444068; called by muse, mutect2, varscan2
- ZC2HC1C | c.526A>G p.R176G | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99472896; called by muse, mutect2, varscan2
- ZNF132 | c.1473T>G p.D491E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99571173; called by muse, mutect2, varscan2
- ZNF253 | c.193A>G p.M65V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1328006717, COSV100849525; called by muse, mutect2
- ZNF346 | c.8A>G p.Y3C | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1450946108, COSV99993221; called by muse, mutect2
- ZNF563 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs764190825, COSV99536617; called by muse, mutect2, varscan2
- ZNF763 | c.653A>G p.H218R (on ENST00000358987 / NM_001367172.2; = p.H221R on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100676122; called by muse, mutect2, varscan2
- APBB1IP | c.806del p.N269Tfs*22 | Frame Shift Del (DEL) | VAF 37/363 reads (10%) | called by mutect2, pindel
- B3GALNT2 | c.1152-1_1163del p.X384_splice | Splice Site (DEL) | VAF 22/165 reads (13%) | called by mutect2, pindel, varscan2
- EXOC4 | c.558_561delinsTTTT p.M186_N187delinsIF | Missense Mutation (ONP) | VAF 8/83 reads (10%) | called by pindel, varscan2*
- FGA | c.492_510+7delinsGAG p.X164_splice | Splice Site (DEL) | VAF 17/57 reads (30%) | called by pindel, varscan2*
- IGF2R | c.4452G>T p.R1484S | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); called by muse, mutect2
- MICALL2 | c.1833_1850del p.L612_A617del | In Frame Del (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- NELFCD | c.1703_1721del p.N568Tfs*11 (on ENST00000602795; = p.N550Tfs*11 on NM_198976.4) | Frame Shift Del (DEL) | VAF 18/149 reads (12%) | called by mutect2, pindel, varscan2
- NOVA1 | c.1433del p.P478Qfs*10 | Frame Shift Del (DEL) | VAF 24/214 reads (11%) | called by mutect2, pindel, varscan2
- PTPRK | c.838del p.V280Cfs*9 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- PVR | c.498_508del p.C166Wfs*60 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- SYNJ1 | c.4511_4542del p.F1504* | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- TAF4B | c.1618del p.E540Kfs*4 | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.1295_1297del p.L432del | In Frame Del (DEL) | VAF 15/149 reads (10%) | called by mutect2, pindel
- UBR1 | c.3039del p.D1013Efs*84 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- ADGRF4 | c.915C>T p.A305= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV99348448; called by muse, mutect2, varscan2
- AHNAK | c.10098A>T p.T3366= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99947721; called by muse, mutect2, varscan2
- ANKRD52 | c.1831C>T p.L611= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs755939369, COSV57288085, COSV99921351; called by muse, mutect2, varscan2
- BAZ1A | c.270A>G p.L90= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as rs761809864, COSV100701158; called by muse, mutect2, varscan2
- CCDC9 | c.894C>T p.T298= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as rs143618657; called by muse, mutect2
- CEMIP | c.1486C>A p.R496= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV99586800; called by muse, mutect2, varscan2
- CNTNAP2 | c.1278C>A p.L426= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV100666942; called by muse, mutect2, varscan2
- CPZ | c.781C>T p.L261= (on ENST00000360986 / NM_001014447.3; = p.L250= on NM_003652.3) | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs971507813, COSV100248997; called by muse, mutect2, varscan2
- DEPDC5 | c.1842A>G p.R614= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99835546; called by muse, mutect2, varscan2
- DIPK1B | c.579A>G p.E193= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV100765466; called by muse, mutect2
- DNAJC22 | c.249C>G p.A83= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as COSV101222543; called by muse, mutect2, varscan2
- EIPR1 | c.1161A>C p.L387= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV101182071; called by muse, mutect2, varscan2
- EPB41L4B | c.483A>G p.R161= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV101000540; called by muse, mutect2, varscan2
- GLI4 | c.546G>A p.P182= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV100391065; called by muse, mutect2, varscan2
- KCTD6 | c.441T>G p.T147= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV100250190; called by muse, mutect2, varscan2
- KDM3B | c.2964A>G p.K988= | Silent (SNP) | VAF 21/159 reads (13%) | catalogued as COSV100069728; called by muse, mutect2, varscan2
- LYST | c.6282A>G p.Q2094= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs749243447, COSV101089607; called by mutect2, varscan2
- MACO1 | c.339A>G p.V113= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs569961532, COSV100975189; called by muse, mutect2, varscan2
- MAN2B2 | c.1168C>T p.L390= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as rs1371097912, COSV99577498; called by muse, mutect2, varscan2
- MED12 | c.4275A>G p.V1425= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100378188; called by muse, mutect2, varscan2
- NEK2 | c.754T>C p.L252= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100878656; called by muse, mutect2, varscan2
- NTRK3 | c.412C>A p.R138= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV100446683; called by muse, mutect2, varscan2
- PCK1 | c.741T>G p.A247= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV100100534; called by muse, mutect2, varscan2
- PLEKHG3 | c.1950A>G p.E650= (on ENST00000394691; = p.E706= on NM_001308147.2) | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99906651; called by muse, mutect2, varscan2
- PTPN5 | c.687C>A p.P229= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- RB1CC1 | c.4509G>T p.V1503= | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as COSV99212304; called by muse, mutect2, varscan2
- RIMS1 | c.4590C>A p.G1530= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs1376609475, COSV99327325; called by muse, mutect2, varscan2
- RUSC2 | c.3030T>C p.H1010= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100770734; called by muse, mutect2, varscan2
- SLC20A2 | c.765A>G p.V255= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs1243792842, COSV100646083; ClinVar: likely benign; called by muse, mutect2, varscan2
- SOX11 | c.21C>T p.S7= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as COSV100431160, COSV58985684; called by muse, mutect2, varscan2
- TENM3 | c.7837C>T p.L2613= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs1443519188, COSV101305160, COSV69302403; called by muse, mutect2, varscan2
- TEP1 | c.36A>T p.P12= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV53001031; called by muse, mutect2
- TFIP11 | c.243C>T p.I81= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV101316467; called by muse, mutect2, varscan2
- TMEM220 | c.450C>G p.S150= | Silent (SNP) | VAF 34/227 reads (15%) | catalogued as COSV100541407; called by muse, mutect2, varscan2
- TREML4 | c.342T>C p.A114= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as COSV100422926; called by muse, mutect2, varscan2
- TRRAP | c.2346C>A p.L782= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100722529; called by muse, mutect2, varscan2
- XPO7 | c.438A>G p.E146= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99381352; called by muse, mutect2
- ZNF85 | c.987T>C p.L329= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV100059849; called by muse, mutect2, varscan2
- NDUFA3 | c.*102A>G | 3'UTR (SNP) | VAF 26/126 reads (21%) | catalogued as COSV100338226; called by muse, mutect2, varscan2
- TTN | c.10303+1059_10303+1067del | Intron (DEL) | VAF 5/62 reads (8%) | called by mutect2, pindel*
